Somatic mutation profile of tumor specimen MP2PRT-PASGZN-TMP1-A (aliquot MP2PRT-PASGZN-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASGZN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,282 days).
Specimen MP2PRT-PASGZN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 942f1cd1-63cd-4373-b217-1ee26010746f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASGZN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASGZN-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a18ed561-9062-4c7d-92dc-7be2de7bc7c1

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2, Frame Shift Ins 2, 5'UTR 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50466733; called by muse, mutect2, varscan2
- HCFC1 | c.307T>C p.Y103H | Missense Mutation (SNP) | VAF 162/408 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM151760; called by muse, mutect2, varscan2
- IGLL1 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.632); catalogued as rs369307571; called by muse, mutect2
- LEMD3 | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1217566272, COSV57651733; called by muse, mutect2
- LRRC28 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 172/353 reads (49%) | catalogued as rs773400802; called by muse, mutect2, varscan2
- MGA | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 144/397 reads (36%) | catalogued as rs1225212904, COSV54950572, COSV54952145; called by muse, mutect2, varscan2
- PEX11A | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 33/387 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs759527990; called by muse, mutect2
- POLE3 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 143/360 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV55914797; called by muse, mutect2, varscan2
- RBMXL3 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 42/694 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.457); catalogued as rs1556560671, COSV57760132; called by muse, mutect2
- COQ5 | c.906A>C p.E302D | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- CREBBP | c.3805_3806insCCCA p.K1269Tfs*6 | Frame Shift Ins (INS) | VAF 12/121 reads (10%) | called by mutect2, pindel, varscan2
- CTCF | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- IGHV3-43 | chr14:106470262 del GTATCTTTTGCACAGTAATACAA | Missense Mutation (DEL) | VAF 10/59 reads (17%) | called by pindel, varscan2
- IGKJ4 | chr2:88860907 CTCCGCCGAAAGTGAGCCAC>TTGA | Missense Mutation (DEL) | VAF 16/67 reads (24%) | called by pindel, varscan2*
- SCARF2 | c.632G>C p.C211S | Missense Mutation (SNP) | VAF 236/554 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBL1XR1 | c.418_421del p.T140* | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | called by pindel*, varscan2
- USP36 | c.2555_2556insCGGTC p.E853Gfs*46 | Frame Shift Ins (INS) | VAF 137/375 reads (37%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.1491G>T p.R497= | Silent (SNP) | VAF 144/569 reads (25%) | called by muse, mutect2, varscan2
- EXOC3L1 | c.1701G>A p.T567= | Silent (SNP) | VAF 30/490 reads (6%) | catalogued as rs371574544, COSV52045938; called by muse, mutect2
- MAP1B | c.993C>T p.L331= | Silent (SNP) | VAF 146/366 reads (40%) | catalogued as rs145044773; called by muse, mutect2, varscan2
- PIK3R5 | c.1407C>T p.P469= | Silent (SNP) | VAF 20/478 reads (4%) | called by muse, mutect2
- IP6K2 | c.-95_-94insGGCCACAACAAG | 5'UTR (INS) | VAF 55/362 reads (15%) | called by mutect2, pindel, varscan2
- PEG10 | c.*348G>A | 3'UTR (SNP) | VAF 25/353 reads (7%) | catalogued as COSV71788767; called by muse, mutect2
